Somatic mutation profile of tumor specimen MMRF_1520_3_BM_CD138pos (aliquot MMRF_1520_3_BM_CD138pos_T1_KBS5U_L05849) from MMRF case MMRF_1520, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.4 years (22,782 days).
Specimen MMRF_1520_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3155f681-a287-43d5-8da9-56d421870af6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1520_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1520_1_PB_Whole_C3_KBS5U_L05564; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c20f861-b3e0-46c1-8d33-7d1662d29d64

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAML2 | c.1974G>A p.Q658= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs571656416, COSV73262854, COSV73262892; called by mutect2, varscan2
- UMODL1 | c.603+24C>T | Intron (SNP) | VAF 3/36 reads (8%) | catalogued as rs1483468468; called by muse, mutect2
